Gene-level copy-number profile of tumor specimen CUPP-B48X-TTM1-A from CCG case CUPP-B48X, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neoplasm, malignant, uncertain whether primary or metastatic; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 51.7 years (18,898 days).
Specimen CUPP-B48X-TTM1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3f67152a-a8de-4137-b3b0-6d89945e6085.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B48X-NT1-A (ffpe scrolls); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/d94501f6-39a3-4b7d-b8a4-e21ef96b6ffc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 2,861; copy number 2: 55,905; copy number 3: 93; copy number 4: 16; copy number 5: 2; copy number 22: 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:916,865–921,016, 1 gene: LINC02593.
- chr1:2,049,203–2,050,070, 1 gene: AL391845.1.
- chr9:97,743,208–97,744,935, 1 gene: AL445531.1.
- chr9:136,410,641–136,423,761, 1 gene: PMPCA.
- chr11:71,448,674–71,452,157, 1 gene (within-gene range 0–2): AP002387.1.
- chr16:1,065,240–1,066,502, 1 gene (within-gene range 0–2): AC009041.2.
- chr19:36,014,508–36,045,972, 2 genes (within-gene range 0–2): AC002116.2, CLIP3.
- chr20:63,696,652–63,708,025, 2 genes (within-gene range 0–2): TNFRSF6B, ARFRP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:135,455,865–135,456,952, 1 gene, copy number 5: AC040914.1.
- chr19:33,302,857–33,305,054, 1 gene, copy number 22 (within-gene range 2–22): CEBPA-DT.

Autosomal genes at a single copy (total copy number 1): 32. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
